Somatic mutation profile of tumor specimen TCGA-97-8176-01A (aliquot TCGA-97-8176-01A-11D-2393-08) from TCGA case TCGA-97-8176, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 63.4 years (23,170 days).
Specimen TCGA-97-8176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 717fc03c-19da-4112-8d65-1df5f9b01d6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-8176-10B (Blood Derived Normal), aliquot TCGA-97-8176-10B-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08dc3e42-c96a-4550-9f7e-f3ae3b4f728b

The open-access MAF lists 166 somatic variants for this specimen: 124 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 39, Nonsense Mutation 14, Splice Site 5, Frame Shift Del 4, Splice Region 2, RNA 2, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2
- SMARCA4 | c.2761C>T p.L921F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs281875228, CM122493, COSV60794202; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABI3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs369657954; called by muse, mutect2, varscan2
- ABLIM3 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV100448349, COSV58649131; called by muse, mutect2, varscan2
- ACAP3 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV100686418; called by muse, mutect2, varscan2
- AHSG | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.858); catalogued as rs1192798742, COSV56608945; called by muse, mutect2, varscan2
- ANK2 | c.8914G>T p.V2972L | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100001508; called by muse, mutect2, varscan2
- ASPM | c.10353G>C p.L3451F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99660325; called by muse, mutect2, varscan2
- ATM | c.5051C>G p.S1684C | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1565473651, COSV99589527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99980732; called by muse, mutect2, varscan2
- AUTS2 | c.1893G>T p.K631N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100716673; called by muse, mutect2, varscan2
- BBS4 | c.691T>A p.Y231N | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV99166438; called by muse, mutect2, varscan2
- BCDIN3D | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1223318754, COSV100445517; called by muse, mutect2, varscan2
- CARS2 | c.770G>T p.C257F | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1202928066, COSV99959624; called by muse, mutect2, varscan2
- CDH10 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100051326; called by muse, mutect2, varscan2
- CKAP4 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs746298180, COSV100952446; called by muse, mutect2, varscan2
- COL18A1 | c.4339C>T p.L1447F (on ENST00000359759 / NM_130444.3; = p.L1212F on NM_030582.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100645234; called by muse, mutect2
- COL21A1 | c.2047G>T p.G683* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99778621; called by muse, mutect2
- COL2A1 | c.4415G>A p.G1472E | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs773418634, COSV56742590; called by muse, mutect2, varscan2
- COL3A1 | c.3431C>G p.P1144R | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100482978, COSV58593514; called by muse, mutect2, varscan2
- CSMD1 | c.8164C>A p.L2722M (on ENST00000520002; = p.L2721M on NM_033225.6) | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as COSV100147476; called by muse, mutect2, varscan2
- CUZD1 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.066); catalogued as rs771478423, COSV100158630, COSV100158748; called by muse, mutect2, varscan2
- CYLC2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100872442; called by muse, mutect2, varscan2
- DCTN1 | c.2656T>A p.Y886N | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV100720942; called by muse, mutect2, varscan2
- DDX20 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100865927; called by muse, mutect2
- DHX29 | c.3948G>T p.W1316C | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287253; called by muse, mutect2, varscan2
- DIAPH3 | c.2060G>T p.C687F (on ENST00000400324 / NM_001042517.2; = p.C424F on NM_030932.3) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99933424; called by muse, mutect2, varscan2
- DOCK10 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99289371; called by muse, mutect2, varscan2
- ECHS1 | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.598); catalogued as rs770614061, COSV100881898; called by muse, mutect2, varscan2
- EVA1B | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs759982436, COSV54634005; called by muse, mutect2, varscan2
- FAM160A2 | c.2746G>A p.G916S (on ENST00000449352 / NM_001098794.2; = p.G930S on NM_032127.4) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs755544760, COSV99792045; called by muse, mutect2, varscan2
- FAM83G | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs969896084, COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FANCM | c.4603G>C p.E1535Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99951025; called by muse, mutect2
- FASN | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100147750; called by muse, mutect2, varscan2
- FCHO1 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 33/200 reads (17%) | catalogued as COSV99406083; called by muse, mutect2, varscan2
- FGD6 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs1276700389, COSV100676560; called by muse, mutect2, varscan2
- FOCAD | c.1455G>T p.Q485H | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100620373; called by muse, mutect2, varscan2
- GAPVD1 | c.2638A>T p.T880S (on ENST00000394104; = p.T907S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV99783153; called by muse, mutect2, varscan2
- GBP4 | c.1707G>A p.K569= | Splice Region (SNP) | VAF 50/156 reads (32%) | catalogued as COSV100864382; called by muse, mutect2, varscan2
- GLIPR2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 112/386 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100936938; called by muse, mutect2, varscan2
- GPR160 | c.145A>C p.N49H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as COSV100576126; called by muse, mutect2
- HECTD4 | c.6421G>A p.A2141T | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs1366019711, COSV101107443; called by muse, mutect2, varscan2
- HELZ2 | c.2476G>A p.E826K (on ENST00000467148 / NM_001037335.2; = p.E257K on NM_033405.3) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1382681611, COSV100915569; called by muse, mutect2, varscan2
- HOXA13 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99763592; called by muse, mutect2
- HOXD13 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV101184272; called by muse, mutect2, varscan2
- HPS6 | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100154866; called by muse, mutect2, varscan2
- IGLV8-61 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs374967441; called by muse, mutect2, varscan2
- ISCA1 | c.136-2A>C p.X46_splice | Splice Site (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100276472; called by muse, mutect2, varscan2
- KBTBD8 | c.814A>T p.N272Y | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV99805643; called by muse, mutect2, varscan2
- KCNJ2 | c.311G>A p.W104* | Nonsense Mutation (SNP) | VAF 41/173 reads (24%) | catalogued as COSV99696354; called by muse, mutect2, varscan2
- KEAP1 | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50295103, COSV99407740; called by muse, mutect2, varscan2
- KRT6B | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99360691, COSV99360858; called by muse, mutect2, varscan2
- KRTAP19-5 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as COSV61858437, COSV61859736; called by muse, mutect2, varscan2
- KRTAP9-2 | c.258C>A p.C86* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV100893179, COSV66646708; called by muse, mutect2, varscan2
- LNP1 | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV101051261; called by muse, mutect2, varscan2
- LSM10 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as rs765518615, COSV100240082, COSV59872292; called by muse, mutect2, varscan2
- LVRN | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100773444; called by muse, mutect2, varscan2
- MET | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV100577207, COSV100577535; called by muse, mutect2, varscan2
- MICAL2 | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.021); catalogued as COSV99811751; called by muse, mutect2, varscan2
- MRTFB | c.2331G>T p.L777F (on ENST00000571589 / NM_001365412.2; = p.L727F on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100371216; called by muse, mutect2, varscan2
- MRTFB | c.2332G>T p.A778S (on ENST00000571589 / NM_001365412.2; = p.A728S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV100371220, COSV57957805; called by muse, mutect2, varscan2
- MST1R | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV99618616; called by muse, mutect2, varscan2
- MUC17 | c.3644G>C p.G1215A | Missense Mutation (SNP) | VAF 66/818 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100073090; called by muse, mutect2
- MUC5B | c.13821del p.S4608Afs*30 | Frame Shift Del (DEL) | VAF 19/137 reads (14%) | catalogued as COSV101500337; called by mutect2, pindel, varscan2
- MYH13 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99353870; called by muse, mutect2, varscan2
- NHLRC2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV100992942; called by muse, mutect2, varscan2
- OR14C36 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100507513; called by muse, mutect2, varscan2
- OR1A1 | c.828C>A p.Y276* | Nonsense Mutation (SNP) | VAF 47/233 reads (20%) | catalogued as COSV100410757; called by muse, mutect2
- OR2T11 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1421844289, COSV100424804; called by muse, mutect2
- OR2T3 | c.941T>G p.M314R | Missense Mutation (SNP) | VAF 58/912 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as COSV100613226; called by muse, mutect2
- OR5L1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 102/398 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61735476; called by muse, varscan2
- PCSK2 | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV99359492; called by muse, mutect2, varscan2
- PCSK2 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99359495; called by muse, mutect2, varscan2
- PGBD1 | c.2164C>T p.Q722* | Nonsense Mutation (SNP) | VAF 41/179 reads (23%) | catalogued as COSV52551840, COSV99460200; called by muse, mutect2, varscan2
- PI4KA | c.5693G>A p.C1898Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226921246, COSV99745920; called by muse, mutect2
- PIK3C2A | c.3831G>C p.Q1277H | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790702; called by muse, mutect2, varscan2
- PIP4K2C | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.088); catalogued as COSV100533564; called by muse, mutect2, varscan2
- PKP1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770845681, COSV99825276; called by muse, mutect2, varscan2
- PLXNA3 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs782633270, COSV100859961; called by muse, mutect2, varscan2
- PRELP | c.973+2T>A p.X325_splice | Splice Site (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100557820; called by muse, mutect2, varscan2
- PRLR | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99184364; called by muse, mutect2
- PSG2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 107/632 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101290475; called by muse, mutect2, varscan2
- RIPPLY2 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100860733; called by muse, mutect2, varscan2
- RNF17 | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.387); catalogued as COSV99693118; called by muse, mutect2, varscan2
- ROBO4 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100127574; called by muse, mutect2, varscan2
- SCUBE2 | c.1116G>C p.R372S | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV100496641; called by muse, varscan2
- SFT2D2 | c.481T>C p.*161Qext*64 | Nonstop Mutation (SNP) | VAF 52/286 reads (18%) | catalogued as COSV99608026; called by muse, mutect2, varscan2
- SLC12A2 | c.1407A>G p.K469= | Splice Region (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99321047; called by muse, mutect2, varscan2
- SLC2A10 | c.1553C>A p.T518N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100826365; called by muse, mutect2, varscan2
- SLC2A6 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV99390255; called by muse, mutect2
- SLC37A4 | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs781834870, COSV100421529; called by muse, mutect2, varscan2
- SLC6A19 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs751730038, COSV58670239; called by muse, mutect2, varscan2
- SLCO2A1 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs764309379, COSV100188952; called by muse, mutect2, varscan2
- SLITRK2 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV59427931; called by muse, mutect2, varscan2
- SMG1 | c.2006A>C p.Y669S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101245933; called by muse, mutect2
- SNX13 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV101285096; called by muse, mutect2
- SORCS3 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100865076, COSV63824205; called by muse, mutect2, varscan2
- SPICE1 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV99871331; called by muse, mutect2, varscan2
- SRPK2 | c.1477G>C p.V493L | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.142); catalogued as COSV100623943; called by muse, mutect2, varscan2
- STAB1 | c.332-1G>A p.X111_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100401692; called by muse, mutect2, varscan2
- TEAD4 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100622025; called by muse, mutect2, varscan2
- TLN2 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1375136175, COSV60893870; called by muse, mutect2, varscan2
- TMEM104 | c.1192G>C p.V398L | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as COSV100120672; called by muse, mutect2, varscan2
- TMEM131L | c.3773G>T p.W1258L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99547345; called by muse, mutect2, varscan2
- TNKS | c.2977G>C p.D993H | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100126931; called by muse, mutect2, varscan2
- TPX2 | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1257604668, COSV100301709; called by muse, mutect2
- TSHZ3 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99551487; called by muse, varscan2
- TTC14 | c.2044G>T p.V682F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.106); catalogued as COSV99868690; called by muse, mutect2, varscan2
- TYK2 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99314709; called by muse, mutect2, varscan2
- UBQLN3 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100293624; called by muse, mutect2, varscan2
- WWP2 | c.1522-1G>A p.X508_splice | Splice Site (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100598540; called by muse, mutect2, varscan2
- XIRP2 | c.2473C>T p.Q825* (on ENST00000628543; = p.Q1000* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 23/137 reads (17%) | catalogued as COSV54701163; called by muse, mutect2, varscan2
- ZNF225 | c.734C>G p.S245* | Nonsense Mutation (SNP) | VAF 34/174 reads (20%) | catalogued as COSV99489440; called by muse, mutect2, varscan2
- ZNF521 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 38/91 reads (42%) | catalogued as COSV100832097; called by muse, mutect2, varscan2
- ZNF521 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100832099; called by muse, mutect2, varscan2
- ZNF619 | c.1070A>C p.E357A | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs916835914, COSV100123174; called by muse, mutect2
- ZNF703 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); catalogued as rs868299390, COSV100521727; called by muse, mutect2
- ZNF804A | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 60/244 reads (25%) | catalogued as COSV100166689, COSV100167753; called by muse, mutect2, varscan2
- ZNF816 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99554574; called by muse, mutect2, varscan2
- AGAP4 | c.994_998del p.I332Hfs*3 | Frame Shift Del (DEL) | VAF 67/162 reads (41%) | called by mutect2, pindel, varscan2
- BACE1 | c.551_567+2del p.X184_splice | Splice Site (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel
- IGSF9B | c.1205C>G p.T402S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.005); called by muse, mutect2
- TJP1 | c.1883_1886del p.T628Sfs*16 | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | called by pindel, varscan2
- TVP23C | c.338del p.S113Ffs*27 | Frame Shift Del (DEL) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- ACAP3 | c.633G>T p.L211= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100686415; called by muse, mutect2, varscan2
- ADAM12 | c.306C>T p.D102= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as rs370718727; called by muse, mutect2, varscan2
- ARFGEF2 | c.1755C>T p.P585= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100904244; called by muse, mutect2, varscan2
- ARHGAP36 | c.829C>T p.L277= | Silent (SNP) | VAF 74/151 reads (49%) | catalogued as rs1309313041, COSV52265580, COSV99357654; called by muse, mutect2, varscan2
- ARL4C | c.564G>A p.Q188= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100326918, COSV60214408; called by muse, varscan2
- ASTN2 | c.870G>T p.L290= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV100527184, COSV57819827; called by muse, mutect2, varscan2
- BRSK2 | c.312C>T p.F104= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs201092064, COSV100372709; called by muse, mutect2
- BTG4 | c.15T>C p.I5= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100604493, COSV63636658; called by muse, mutect2, varscan2
- C2orf16 | c.1542A>G p.K514= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as COSV100820788; called by muse, mutect2, varscan2
- CENPP | c.510G>T p.L170= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV99364075; called by muse, mutect2, varscan2
- DLGAP4 | c.2052C>T p.P684= (on ENST00000339266 / NM_001365621.1; = p.P145= on NM_183006.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs776373303, COSV100211189, COSV100211403; called by muse, mutect2, varscan2
- DMXL2 | c.4266G>A p.E1422= | Silent (SNP) | VAF 13/256 reads (5%) | catalogued as COSV99196336; called by muse, mutect2
- DNAH17 | c.10224C>T p.D3408= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs1341222838, COSV101101704; called by muse, mutect2, varscan2
- DOCK2 | c.1701C>A p.T567= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99912191; called by muse, mutect2, varscan2
- DOK5 | c.357C>A p.I119= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as COSV99373821; called by muse, mutect2, varscan2
- FAT3 | c.13491C>A p.G4497= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV99965802; called by muse, mutect2, varscan2
- FLII | c.1089G>A p.T363= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs148245851; called by muse, mutect2, varscan2
- GLI1 | c.837G>A p.L279= | Silent (SNP) | VAF 8/227 reads (4%) | called by muse, mutect2
- GTF3C1 | c.4710C>T p.A1570= | Silent (SNP) | VAF 27/191 reads (14%) | catalogued as rs1295737251, COSV100649379; called by muse, mutect2, varscan2
- HIPK1 | c.819G>A p.Q273= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV101060382; called by muse, mutect2, varscan2
- HS3ST2 | c.363C>A p.G121= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs140526711, COSV54460050; called by muse, mutect2, varscan2
- HSPH1 | c.259T>C p.L87= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV100184913; called by muse, mutect2, varscan2
- LVRN | c.57G>A p.L19= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100773443; called by mutect2, varscan2
- MUC16 | c.11173C>T p.L3725= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs1397180342, COSV101199841; called by muse, mutect2
- MYO1D | c.246G>A p.A82= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs142146727; called by muse, mutect2, varscan2
- NEIL3 | c.1455T>A p.S485= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV52812827, COSV99220412; called by muse, mutect2, varscan2
- OR2T12 | c.720T>C p.S240= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV100527748; called by muse, mutect2
- PCDHA7 | c.1869C>A p.R623= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV65346451, COSV65347632; called by muse, mutect2, varscan2
- PEX5L | c.969C>T p.F323= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV99828628; called by muse, mutect2, varscan2
- PHACTR3 | c.1188G>C p.R396= | Silent (SNP) | VAF 96/415 reads (23%) | catalogued as COSV100732545; called by muse, mutect2, varscan2
- PTPN14 | c.267C>T p.F89= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs1303010908, COSV100872543; called by muse, mutect2, varscan2
- RTEL1 | c.1518C>T p.I506= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs757231662, COSV58897926; called by muse, mutect2, varscan2
- SLC43A3 | c.222C>T p.F74= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100725193; called by muse, mutect2, varscan2
- USH2A | c.10434C>A p.A3478= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100234191; called by muse, mutect2, varscan2
- UTP14C | c.288A>T p.S96= | Silent (SNP) | VAF 35/215 reads (16%) | catalogued as COSV101584286; called by muse, mutect2, varscan2
- UTP20 | c.2532G>A p.P844= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as rs768715409, COSV55375255; called by muse, mutect2, varscan2
- ZFP36 | c.546C>G p.G182= (on ENST00000594442; = p.G176= on NM_003407.5) | Silent (SNP) | VAF 32/178 reads (18%) | catalogued as COSV99953794; called by muse, mutect2, varscan2
- ZGPAT | c.267G>T p.A89= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100157577; called by muse, mutect2, varscan2
- ZNF629 | c.1320C>A p.I440= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV99354778; called by muse, mutect2, varscan2
- LINC01559 | n.533G>A | RNA (SNP) | VAF 67/325 reads (21%) | called by muse, mutect2, varscan2
- OR2U1P | n.97T>C | RNA (SNP) | VAF 57/225 reads (25%) | catalogued as rs766219580; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23244C>T | Intron (SNP) | VAF 61/337 reads (18%) | catalogued as COSV59399351; called by muse, mutect2, varscan2
